Surgical pathology report (de-identified scan), TCGA case TCGA-BR-6706, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-6706-01A (Primary Tumor).

[page 1 of 2]
Formatted Path Report

STOMACH TISSUE CHECKLIST

Specimen type: Subtotal gastrectomy
Tumor site: Stomach
Tumor size: 7.5 x 0 x 8.5 cm
Tumor features: Ulcerated
Histologic type: Adenocarcinoma
Histologic grade: Poorly differentiated
Tumor extent: Subserosa
Lymph nodes: 5/15 positive for metastasis (Lesser and greater curvature omentum 5/15)
Lymphatic invasion: Not specified
Venous invasion: Absent
Perineural invasion: Not specified
Margins: Uninvolved
Evidence of neo-adjuvant treatment: Not specified
Additional pathologic findings: Not specified
Comments: None

[page 2 of 2]
Date of Procurement

Source: NCI Genomic Data Commons file 880f901a-d19f-4c0d-be57-d9af5a8a6c61 (TCGA-BR-6706.FF40DC7A-F941-40DC-88A3-124CCACB5BC4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).